Somatic mutation profile of tumor specimen TCGA-AA-A01P-01A (aliquot TCGA-AA-A01P-01A-21W-A096-10) from TCGA case TCGA-AA-A01P, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage III; Age at diagnosis: 80.9 years (29,554 days).
Specimen TCGA-AA-A01P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4316c066-5dd1-44fe-90d2-5dc66b46be12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A01P-11A (Solid Tissue Normal), aliquot TCGA-AA-A01P-11A-11D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83f536df-fcb8-42d5-a89f-d9dc1711f42e

The open-access MAF lists 691 somatic variants for this specimen: 534 protein-altering or splice-affecting, 145 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 365, Silent 145, Frame Shift Del 104, Nonsense Mutation 23, Frame Shift Ins 19, Splice Site 10, Splice Region 6, In Frame Del 6, Intron 6, RNA 4, 3'UTR 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMELX | c.499del p.L167Cfs*8 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs387906490; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BMPR1A | c.176del p.L59* | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | catalogued as rs786201038; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GRIN2A | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397518468, CM138212, COSV58031541; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NPC1 | c.2978del p.G993Efs*4 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs775915490, CD053590, COSV99342140; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NPC1 | c.631+2T>C p.X211_splice | Splice Site (SNP) | VAF 35/180 reads (19%) | catalogued as rs1555638833, COSV99341263; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 12/80 reads (15%) | hotspot (GDC flag); called by pindel, varscan2
- RHOA | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 12/78 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69041545, COSV69041670; called by muse, mutect2, varscan2
- TJP2 | c.2438del p.F813Sfs*12 | Frame Shift Del (DEL) | VAF 36/176 reads (20%) | catalogued as rs776869985; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AC098582.1 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV99985542; called by muse, mutect2, varscan2
- ACADSB | c.594T>A p.Y198* | Nonsense Mutation (SNP) | VAF 53/175 reads (30%) | catalogued as COSV100715180; called by muse, mutect2, varscan2
- ACE2 | c.971C>G p.T324S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as COSV99382759; called by muse, mutect2, varscan2
- ADAM11 | c.2204T>C p.I735T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99567433; called by muse, mutect2, varscan2
- ADAMTS19 | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50732749, COSV50746318; called by muse, mutect2, varscan2
- ADAMTS5 | c.2440A>G p.R814G | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.341); catalogued as COSV99537530; called by muse, mutect2, varscan2
- ADGRG3 | c.799A>T p.I267F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV100342350; called by muse, mutect2, varscan2
- AFF3 | c.3301G>A p.A1101T | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs771583669, COSV100418731; called by muse, mutect2, varscan2
- AFM | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 71/457 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs199782653, COSV56919520; called by muse, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | catalogued as rs779815391; called by mutect2, varscan2
- AL669918.1 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV101441043; called by muse, mutect2, varscan2
- ALDH18A1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs773903524, COSV100973155; called by muse, mutect2, varscan2
- ALOX12 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52352835; called by muse, mutect2, varscan2
- AMELX | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100497946; called by mutect2, varscan2
- AMOT | c.2525C>A p.S842* (on ENST00000371959 / NM_001113490.1; = p.S433* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV100494995, COSV100495007; called by muse, mutect2, varscan2
- ANGPTL2 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs935179408, COSV99401540; called by muse, mutect2, varscan2
- ANK1 | c.2512G>A p.D838N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55892464; called by muse, mutect2, varscan2
- ANK2 | c.5275G>A p.E1759K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100001408; called by muse, mutect2, varscan2
- ANK3 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55086348; called by muse, varscan2
- ANKFY1 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1177246007, COSV58920284; called by muse, mutect2, varscan2
- ANKRD50 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV101538945; called by muse, mutect2, varscan2
- ANKRD53 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1006652499, COSV99721351; called by muse, mutect2, varscan2
- ANKS1B | c.2329A>G p.T777A | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.956); catalogued as COSV100245248; called by muse, mutect2, varscan2
- ANO4 | c.1441C>T p.R481W (on ENST00000392977 / NM_001286615.2; = p.R446W on NM_178826.4) | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs765804915, COSV54602170; called by muse, mutect2, varscan2
- ANTXR2 | c.1123A>C p.T375P | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56320622; called by muse, mutect2, varscan2
- AP1G2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs200202756; called by muse, mutect2, varscan2
- AP1M2 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV99140815; called by muse, mutect2, varscan2
- APBB2 | c.2140C>T p.P714S (on ENST00000295974 / NM_001166050.2; = p.P715S on NM_004307.2) | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99922951; called by muse, mutect2, varscan2
- APOA4 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs549843769, COSV100759315; called by mutect2, varscan2
- APOB | c.4250C>T p.T1417M | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.147); catalogued as rs200321839, COSV51928643; called by muse, mutect2, varscan2
- ARFIP1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 80/459 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs145188297; called by muse, mutect2, varscan2
- ARHGEF10 | c.1240G>A p.G414S (on ENST00000398564; = p.G389S on NM_014629.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV50686438; called by muse, mutect2, varscan2
- ARHGEF10 | c.2878A>G p.M960V (on ENST00000398564; = p.M935V on NM_014629.4) | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100034438; called by muse, mutect2, varscan2
- ARHGEF40 | c.1891C>A p.L631I | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100070295; called by muse, mutect2, varscan2
- ARL8B | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99848618; called by muse, mutect2, varscan2
- ASH1L | c.7582C>T p.R2528C (on ENST00000368346 / NM_001366177.2; = p.R2523C on NM_018489.3) | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs1376913986, COSV64208707; called by muse, mutect2, varscan2
- ATAD5 | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1004100672, COSV58974436; called by muse, mutect2, varscan2
- ATP4A | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV99382523; called by muse, mutect2, varscan2
- ATXN2L | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs560637561, COSV100294253; called by muse, varscan2
- B4GALT5 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 59/385 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100866994; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs768244116; called by mutect2, varscan2
- BFAR | c.763dup p.Q255Pfs*7 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs781267226; called by mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 21/127 reads (17%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC2 | c.1428C>A p.C476* | Nonsense Mutation (SNP) | VAF 21/143 reads (15%) | catalogued as COSV101033083; called by muse, mutect2, varscan2
- BPIFB6 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.305); catalogued as COSV100848511; called by muse, varscan2
- BRINP3 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs763233124, COSV66534847; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | catalogued as rs1455506786, COSV59000653; called by mutect2, varscan2
- BRWD3 | c.1283T>C p.M428T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV100955982; called by muse, mutect2, varscan2
- BTBD1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.196); catalogued as COSV99915451; called by muse, mutect2, varscan2
- BUB1 | c.1856T>C p.V619A | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100241220; called by muse, mutect2, varscan2
- C14orf93 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs758103437, COSV54441813; called by muse, mutect2, varscan2
- C17orf78 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as rs369234656; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 51/280 reads (18%) | catalogued as rs1558068270; called by mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 42/296 reads (14%) | catalogued as rs372345940; called by mutect2, varscan2
- CACNB2 | c.1018G>A p.A340T (on ENST00000324631 / NM_201596.3; = p.A285T on NM_000724.4) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.479); catalogued as rs140614930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADPS2 | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100462559; called by muse, mutect2, varscan2
- CARD6 | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs183932779; called by muse, mutect2, varscan2
- CASP14 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs751321912, COSV99693009; called by muse, mutect2, varscan2
- CCDC141 | c.3268A>T p.I1090F | Missense Mutation (SNP) | VAF 79/478 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV55384336; called by muse, mutect2, varscan2
- CCDC180 | c.4614del p.K1539Nfs*17 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs1423532083; called by mutect2, pindel, varscan2
- CCDC65 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99872764; called by muse, mutect2, varscan2
- CCDC73 | c.208-2A>G p.X70_splice | Splice Site (SNP) | VAF 116/609 reads (19%) | catalogued as COSV100067304; called by muse, mutect2, varscan2
- CCNT1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs575488596, COSV56066300; called by muse, mutect2, varscan2
- CD109 | c.3192T>C p.P1064= | Splice Region (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99753472; called by muse, mutect2, varscan2
- CD46 | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747504551, COSV100522868; called by muse, mutect2, varscan2
- CD46 | c.735del p.K245Nfs*53 | Frame Shift Del (DEL) | VAF 35/180 reads (19%) | catalogued as rs1343140692; called by mutect2, varscan2
- CDC27 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV50707129; called by muse, mutect2, varscan2
- CDC40 | c.1085A>C p.E362A | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100309273; called by muse, mutect2, varscan2
- CDH11 | c.1159A>G p.S387G | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV99218206; called by muse, varscan2
- CDH7 | c.982-2A>C p.X328_splice | Splice Site (SNP) | VAF 28/117 reads (24%) | catalogued as COSV100542244; called by muse, mutect2, varscan2
- CDK12 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1488101050, COSV71000036; called by muse, mutect2, varscan2
- CEP162 | c.2761dup p.I921Nfs*9 | Frame Shift Ins (INS) | VAF 192/992 reads (19%) | catalogued as rs1562026955; called by mutect2, varscan2
- CEP290 | c.6147A>G p.I2049M | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV100468599; called by muse, mutect2, varscan2
- CEP83 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs759737051; called by muse, mutect2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 17/116 reads (15%) | catalogued as rs768479535; called by mutect2, varscan2
- CES5A | c.352T>C p.S118P | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99307484; called by muse, mutect2, varscan2
- CFAP299 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs765782959, COSV63872319; called by muse, varscan2
- CHD9 | c.6019G>A p.A2007T | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99529109; called by muse, mutect2, varscan2
- CHST10 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as rs148953500; called by muse, mutect2, varscan2
- CILP | c.2645G>T p.R882M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV56024902; called by muse, mutect2, varscan2
- CLDN8 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs778089405, COSV54525752; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs758841384; called by mutect2, pindel, varscan2
- CMYA5 | c.959A>G p.H320R | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs371803314, COSV71409648; called by muse, mutect2, varscan2
- CNNM1 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs761658293, COSV63202446; called by muse, mutect2, varscan2
- CNTN3 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 26/124 reads (21%) | catalogued as COSV99724234; called by muse, mutect2, varscan2
- COL14A1 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs200320717; called by muse, mutect2, varscan2
- COL15A1 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1057094442, COSV100897628; called by muse, mutect2, varscan2
- COL4A5 | c.3632G>T p.G1211V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM960390, COSV100087562; called by muse, mutect2, varscan2
- COL9A1 | c.1178del p.P393Lfs*36 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | catalogued as rs1482734025, COSV57884567; called by mutect2, pindel, varscan2
- CORO2B | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs370083446, COSV55951128; called by muse, mutect2, varscan2
- CPEB4 | c.1962+2T>C p.X654_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | catalogued as COSV54177007; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 52/286 reads (18%) | catalogued as rs747832403; called by mutect2, varscan2
- CRYGS | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV100329981; called by muse, mutect2, varscan2
- CSF3R | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs754176065, COSV58963648, COSV58964839; called by muse, mutect2, varscan2
- CSMD1 | c.8407G>T p.V2803L (on ENST00000520002; = p.V2802L on NM_033225.6) | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.629); catalogued as COSV59349219; called by muse, mutect2, varscan2
- CST1 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | catalogued as rs756924682; called by mutect2, pindel, varscan2
- CTAGE1 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV66945319; called by muse, mutect2, varscan2
- CYLC1 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV61416019; called by muse, mutect2, varscan2
- CYP2A6 | c.1082G>T p.R361I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199522873, COSV99991825, COSV99991837; called by muse, mutect2, varscan2
- CYP2S1 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs755173146, COSV100027450; called by muse, mutect2, varscan2
- DACT1 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100241820; called by muse, mutect2, varscan2
- DCAF7 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60407070; called by muse, mutect2, varscan2
- DCLRE1A | c.2599A>G p.T867A | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV100800337; called by muse, mutect2, varscan2
- DCP2 | c.1234A>G p.N412D | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV101203877; called by muse, mutect2, varscan2
- DDX58 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.203); catalogued as rs751722546, COSV59378519; called by muse, mutect2, varscan2
- DDX60L | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV99487546; called by muse, mutect2, varscan2
- DEGS1 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV100083342; called by muse, mutect2, varscan2
- DENND1A | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs766053621, COSV101010556; called by mutect2, varscan2
- DGKH | c.2539G>A p.V847M | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229586089, COSV99818731; called by muse, varscan2
- DIS3L | c.2861G>A p.R954K (on ENST00000319212 / NM_001143688.3; = p.R871K on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV56020880, COSV99972361; called by muse, mutect2, varscan2
- DLEC1 | c.1554G>A p.W518* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV100342148; called by muse, mutect2, varscan2
- DLG3 | c.1441C>T p.R481* (on ENST00000374360 / NM_021120.4; = p.R144* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 42/260 reads (16%) | catalogued as rs1028686595, COSV99529475; called by muse, mutect2, varscan2
- DMD | c.2172G>T p.L724F | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55906895; called by muse, mutect2, varscan2
- DMXL1 | c.7121C>T p.S2374L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100223850; called by muse, mutect2, varscan2
- DNAH7 | c.3512G>A p.R1171Q | Missense Mutation (SNP) | VAF 86/354 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746376803, COSV56753545, COSV56758533; called by muse, mutect2, varscan2
- DOCK6 | c.898C>A p.L300M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.54); catalogued as COSV52949825; called by muse, mutect2, varscan2
- DST | c.409T>G p.F137V | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100418627, COSV56852760; called by muse, mutect2, varscan2
- DSTN | c.272C>T p.T91I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99855142; called by muse, mutect2, varscan2
- DTD2 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100180084; called by muse, mutect2, varscan2
- ECPAS | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as rs760760389, COSV52211443; called by muse, mutect2, varscan2
- ECT2L | c.155T>A p.L52* | Nonsense Mutation (SNP) | VAF 21/212 reads (10%) | catalogued as rs577253266, COSV62882917, COSV62885423; called by muse, mutect2
- EEF1AKNMT | c.1379C>T p.P460L (on ENST00000361735 / NM_015935.5; = p.P374L on NM_014955.3) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs144305462; called by muse, mutect2, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- EFR3A | c.1546del p.C516Afs*8 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | catalogued as COSV54462614; called by mutect2, varscan2
- EHD2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54407896, COSV99621506; called by muse, mutect2, varscan2
- EIF2B4 | c.509G>A p.R170Q (on ENST00000347454 / NM_001034116.2; = p.R169Q on NM_015636.3) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as rs1439504604, COSV99277553; called by muse, mutect2
- EML5 | c.5297C>T p.S1766F (on ENST00000380664; = p.S1774F on NM_183387.3) | Missense Mutation (SNP) | VAF 92/570 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100715558, COSV61341356; called by muse, varscan2
- EML5 | c.3653A>G p.K1218R | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs758429917, COSV100715561; called by muse, mutect2, varscan2
- ENDOU | c.1165T>C p.W389R (on ENST00000422538 / NM_001172439.2; = p.W348R on NM_006025.4) | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99139286; called by muse, mutect2, varscan2
- ENTPD4 | c.1312A>G p.T438A | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs780208873, COSV62269210; called by muse, mutect2, varscan2
- EPB41L2 | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440630; called by muse, mutect2, varscan2
- ERC2 | c.2770C>T p.H924Y | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV99884128; called by muse, mutect2, varscan2
- ERN2 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99890578, COSV99891413; called by muse, mutect2, varscan2
- ESRP1 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.316); catalogued as COSV64410882; called by muse, mutect2, varscan2
- ETV3L | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs765556753, COSV71901012, COSV71901134; called by muse, mutect2, varscan2
- EXOC1 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as rs759005498; called by muse, mutect2
- EZHIP | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100539660; called by muse, mutect2, varscan2
- FAM135B | c.3922G>A p.V1308I | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.928); catalogued as rs759696683, COSV52702423; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM162A | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99216348; called by muse, mutect2, varscan2
- FAM24A | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV100925080; called by muse, mutect2, varscan2
- FANCM | c.4418A>T p.N1473I | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99950990; called by muse, varscan2
- FBH1 | c.401C>A p.A134D (on ENST00000362091 / NM_178150.3; = p.A185D on NM_032807.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.069); catalogued as rs1317810663, COSV100758726; called by muse, mutect2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO24 | c.1033del p.L345Wfs*45 (on ENST00000241071 / NM_033506.3; = p.L383Wfs*45 on NM_012172.5) | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs1236194155; called by mutect2, pindel, varscan2
- FEZF2 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99334682; called by muse, mutect2, varscan2
- FGD2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs367888863; called by mutect2, varscan2
- FHDC1 | c.1315del p.T439Pfs*2 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | catalogued as rs1303890230; called by mutect2, pindel, varscan2
- FIGN | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as rs750122544, COSV100292303; called by muse, mutect2, varscan2
- FKBP10 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs782261801, COSV58636752; called by muse, mutect2
- FLRT2 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100420348; called by muse, mutect2, varscan2
- FN1 | c.4071T>C p.G1357= | Splice Region (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100117041; called by muse, mutect2, varscan2
- FNDC3A | c.3239A>G p.Y1080C (on ENST00000492622 / NM_001079673.2; = p.Y1024C on NM_014923.5) | Missense Mutation (SNP) | VAF 78/411 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101256705; called by muse, mutect2, varscan2
- FOXO4 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.091); catalogued as COSV100446879; called by muse, varscan2
- FRAS1 | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.397); catalogued as COSV53655798; called by muse, mutect2, varscan2
- FRMPD4 | c.1856A>C p.E619A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV101042771; called by muse, mutect2, varscan2
- FRRS1 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 113/466 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV99789858; called by muse, mutect2, varscan2
- FRY | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 86/403 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.78); catalogued as COSV100969182; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as rs908264837; called by pindel, varscan2
- FYN | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991286, COSV99991657; called by muse, mutect2, varscan2
- GABRB2 | c.661A>C p.K221Q | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV99195982; called by muse, mutect2, varscan2
- GABRE | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV64821776; called by muse, mutect2, varscan2
- GALNT15 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 93/355 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs756197962, COSV60217033; called by muse, mutect2, varscan2
- GALNTL6 | c.822A>C p.Q274H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101560261; called by muse, mutect2, varscan2
- GANAB | c.1840G>A p.V614M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as rs770506502, COSV60463395; called by muse, mutect2, varscan2
- GATAD2B | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64083908; called by muse, mutect2, varscan2
- GBF1 | c.146T>G p.V49G | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV100890462; called by muse, mutect2, varscan2
- GCC2 | c.4988A>G p.E1663G | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100474785; called by muse, mutect2, varscan2
- GCSAML | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100825942; called by muse, mutect2, varscan2
- GDAP1L1 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs749288709, COSV100697551; called by muse, mutect2, varscan2
- GGT5 | c.866del p.G289Vfs*11 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as COSV54073059; called by mutect2, varscan2
- GLA | c.782del p.G261Vfs*8 | Frame Shift Del (DEL) | VAF 33/138 reads (24%) | catalogued as CM138881, CM972905; called by mutect2, pindel, varscan2
- GLG1 | c.979-2A>G p.X327_splice | Splice Site (SNP) | VAF 17/187 reads (9%) | catalogued as COSV99215709; called by muse, mutect2
- GLI2 | c.1732G>A p.V578I (on ENST00000361492 / NM_001374353.1; = p.V595I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as rs768557650, COSV58043749; called by muse, mutect2, varscan2
- GOLM1 | c.539dup p.N182Efs*2 | Frame Shift Ins (INS) | VAF 73/443 reads (16%) | catalogued as COSV57413786, COSV57413907; called by mutect2, pindel, varscan2
- GPRASP2 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs759518487, COSV59991256, COSV59992544; called by muse, mutect2, varscan2
- GRIK3 | c.2316C>T p.G772= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100901930; called by muse, mutect2, varscan2
- GSK3A | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55899756; called by muse, mutect2, varscan2
- GTF2F1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201557731, COSV101081058; called by muse, mutect2, varscan2
- GUCY2F | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 56/282 reads (20%) | catalogued as COSV99484918; called by muse, mutect2, varscan2
- HDAC7 | c.2137G>A p.G713S (on ENST00000427332; = p.G752S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747647941, COSV99316089; called by muse, mutect2, varscan2
- HDLBP | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 41/296 reads (14%) | catalogued as COSV100190457, COSV100191452; called by muse, mutect2, varscan2
- HEATR1 | c.6218C>T p.T2073M | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs200854169, COSV100120451; called by muse, mutect2, varscan2
- HEATR5B | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372034610; called by muse, mutect2, varscan2
- HECTD4 | c.6209G>A p.R2070H | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66387540; called by muse, mutect2, varscan2
- HEMGN | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs142085732; called by muse, mutect2, varscan2
- HIF1AN | c.484T>G p.F162V | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100142668; called by muse, mutect2, varscan2
- HUWE1 | c.12437T>C p.M4146T | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99472031; called by muse, varscan2
- IFT80 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs535870220, COSV100424679, COSV58447488; called by muse, mutect2, varscan2
- IGSF10 | c.3148del p.S1050Afs*12 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs34882912; called by mutect2, pindel, varscan2
- IL25 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs375340039; called by muse, mutect2, varscan2
- IRF6 | c.171del p.F57Lfs*6 | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | catalogued as CM097106; called by pindel, varscan2
- ITGB1 | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 141/700 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56487708; called by muse, mutect2, varscan2
- ITIH1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs767332893, COSV99835195, COSV99835271; called by muse, mutect2, varscan2
- ITK | c.37A>G p.K13E | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101439702; called by muse, mutect2, varscan2
- JADE1 | c.1106G>A p.S369N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99885717; called by muse, mutect2, varscan2
- KAT8 | c.1198C>A p.L400M | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99571409; called by muse, mutect2, varscan2
- KCNAB1 | c.276-2A>G p.X92_splice (on ENST00000490337 / NM_172160.3; = p.X81_splice on NM_003471.3) | Splice Site (SNP) | VAF 31/211 reads (15%) | catalogued as COSV100204252; called by muse, mutect2, varscan2
- KIF2B | c.626del p.P209Rfs*10 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV52136659; called by mutect2, pindel, varscan2
- KIF4B | c.3475C>T p.P1159S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772431228, COSV70531901; called by muse, mutect2, varscan2
- KIF9 | c.1796A>T p.N599I (on ENST00000265529 / NM_001377474.1; = p.N534I on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV99646657; called by muse, mutect2
- KLHL1 | c.2135C>T p.T712I | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1251808901, COSV64775972; called by muse, mutect2, varscan2
- KLHL23 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.1); catalogued as COSV99775759; called by muse, mutect2, varscan2
- KLHL4 | c.1160G>T p.S387I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1282305368, COSV100909509; called by muse, mutect2, varscan2
- KLHL8 | c.1014C>A p.C338* | Nonsense Mutation (SNP) | VAF 15/147 reads (10%) | catalogued as COSV99911351; called by muse, mutect2, varscan2
- KMT2E | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99996259; called by muse, mutect2, varscan2
- KPRP | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as rs779553667, COSV64222995; called by muse, mutect2
- KREMEN1 | c.850G>A p.G284R (on ENST00000407188; = p.G286R on NM_032045.5) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs751542642, COSV59911527; called by muse, mutect2, varscan2
- L1CAM | c.3433C>T p.R1145C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200798819, COSV100649090; called by mutect2, varscan2
- LAMB1 | c.5125del p.T1709Lfs*22 | Frame Shift Del (DEL) | VAF 53/285 reads (19%) | catalogued as rs1441388757; called by mutect2, pindel, varscan2
- LAPTM4A | c.525del p.F175Lfs*5 | Frame Shift Del (DEL) | VAF 44/231 reads (19%) | catalogued as rs1476796878; called by mutect2, pindel, varscan2
- LCP1 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100549852; called by muse, mutect2
- LEPROTL1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs974543255, COSV58304364, COSV58304994; called by muse, mutect2, varscan2
- LINGO2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs1016504624, COSV58064143; called by muse, mutect2, varscan2
- LMOD2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV71755718; called by muse, mutect2
- LNX1 | c.388G>A p.G130S (on ENST00000263925 / NM_001126328.3; = p.G34S on NM_032622.2) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99819922; called by muse, mutect2, varscan2
- LRFN5 | c.866T>G p.I289S | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99983628; called by muse, mutect2, varscan2
- LRP10 | c.1466A>T p.Q489L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs555449943; called by mutect2, varscan2
- LRP2 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749942746, COSV55543681; called by muse, mutect2, varscan2
- LRR1 | c.737G>A p.C246Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100023100; called by muse, mutect2, varscan2
- LRRC36 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV99338674; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs1557715031, COSV58440688; called by pindel, varscan2
- LRRC66 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV58636381, COSV58636463; called by muse, varscan2
- LRRK2 | c.3068T>C p.L1023P | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110050, COSV54169871; called by muse, mutect2, varscan2
- LRRN3 | c.1268T>A p.I423K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100070198; called by muse, mutect2, varscan2
- LTBP2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765793427, COSV100000207; called by muse, varscan2
- LUZP1 | c.422T>G p.L141R | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100034846; called by muse, mutect2, varscan2
- M6PR | c.159A>C p.K53N | Missense Mutation (SNP) | VAF 32/624 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV99134173; called by muse, mutect2
- MAB21L3 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.373); catalogued as COSV101046373; called by muse, mutect2
- MAEL | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV63305855; called by muse, mutect2, varscan2
- MAP2K6 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 24/150 reads (16%) | catalogued as rs753824437, COSV100765074; called by muse, mutect2, varscan2
- MAP3K4 | c.4514C>T p.T1505I | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815321; called by muse, mutect2, varscan2
- MASP1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1170038123, COSV99397137; called by muse, mutect2, varscan2
- MAST4 | c.2071C>T p.H691Y (on ENST00000403625 / NM_001164664.2; = p.H502Y on NM_015183.3) | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844027; called by muse, mutect2, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | catalogued as rs1203662025; called by mutect2, varscan2
- MEAK7 | c.688C>A p.L230M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100640394; called by muse, mutect2, varscan2
- MEPE | c.831A>C p.E277D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV63073930; called by muse, mutect2, varscan2
- MLH1 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM123004, COSV51615129, COSV99212419; called by muse, mutect2, varscan2
- MLNR | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as COSV99519825; called by muse, mutect2, varscan2
- MMS19 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs927043964, COSV100512831; called by muse, mutect2, varscan2
- MOGAT2 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs776690691, COSV52220556; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 46/204 reads (23%) | catalogued as rs757379917; called by mutect2, varscan2
- MT1G | c.185C>T p.A62V (on ENST00000379811 / NM_001301267.2; = p.A61V on NM_005950.3) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.399); catalogued as COSV60091778; called by muse, mutect2, varscan2
- MTHFD1L | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs139147258; called by muse, mutect2, varscan2
- MUC16 | c.3560C>G p.T1187S | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV101199710; called by muse, mutect2, varscan2
- MUC21 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761798063, COSV66220632; called by muse, mutect2, varscan2
- MVB12A | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1473494833, COSV100396492; called by muse, varscan2
- MYH7 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100806052; called by muse, mutect2, varscan2
- MYH8 | c.2446T>G p.C816G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV101238393; called by muse, mutect2, varscan2
- MYO18A | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV62874873; called by muse, mutect2, varscan2
- MYO9A | c.2522+1G>A p.X841_splice | Splice Site (SNP) | VAF 48/229 reads (21%) | catalogued as COSV100613341; called by muse, mutect2, varscan2
- MYOCD | c.374dup p.N125Kfs*16 | Frame Shift Ins (INS) | VAF 26/107 reads (24%) | catalogued as rs1567587048; called by mutect2, varscan2
- NAPB | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100582498; called by muse, mutect2, varscan2
- NAPSA | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs186910155, COSV99515824; called by muse, mutect2, varscan2
- NCKAP1 | c.2321A>G p.Q774R | Missense Mutation (SNP) | VAF 100/530 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV100720208; called by muse, mutect2, varscan2
- NCOA7 | c.2698C>T p.R900* | Nonsense Mutation (SNP) | VAF 33/187 reads (18%) | catalogued as rs1300236722, COSV99997042; called by muse, mutect2, varscan2
- NEK9 | c.2906T>G p.L969R | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99464015; called by muse, mutect2, varscan2
- NEMF | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100027606; called by muse, mutect2, varscan2
- NFATC2 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs867932067, COSV65356193; called by muse, mutect2, varscan2
- NHS | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 117/590 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs771048907, COSV66273272; called by muse, mutect2, varscan2
- NIPAL4 | c.1138T>C p.Y380H | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1210461038, COSV57440675; called by muse, mutect2, varscan2
- NIPSNAP2 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 90/464 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100436695; called by muse, mutect2, varscan2
- NKIRAS2 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as rs781878749, COSV100288809; called by muse, mutect2, varscan2
- NLRP4 | c.2834T>G p.L945R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56725060; called by muse, varscan2
- NOL6 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs369599517; called by muse, mutect2, varscan2
- NT5E | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs775412849, COSV57630435; called by muse, mutect2, varscan2
- NUP107 | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 73/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99971715; called by muse, mutect2, varscan2
- NUP160 | c.1686+2T>C p.X562_splice | Splice Site (SNP) | VAF 49/317 reads (15%) | catalogued as COSV101021455; called by muse, mutect2, varscan2
- NUP205 | c.1199T>A p.L400H | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99606939; called by muse, mutect2, varscan2
- ODF2 | c.1084C>T p.R362C (on ENST00000434106 / NM_153433.2; = p.R338C on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186052648, COSV63548498; called by muse, mutect2, varscan2
- OR1G1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1419481787, COSV100187539; called by muse, mutect2, varscan2
- OR51M1 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 121/558 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100150228; called by muse, mutect2, varscan2
- OR5W2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV100747610; called by muse, mutect2, varscan2
- OR6N1 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs751230252, COSV100625157; called by muse, mutect2, varscan2
- OSBPL10 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); catalogued as rs367556908, COSV67338559; called by muse, mutect2, varscan2
- OXNAD1 | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 81/440 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99551195; called by muse, mutect2, varscan2
- PACSIN2 | c.621G>C p.K207N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99606176; called by muse, mutect2, varscan2
- PAPPA2 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.099); catalogued as COSV62788354; called by muse, mutect2, varscan2
- PARD3 | c.2020G>C p.G674R | Missense Mutation (SNP) | VAF 19/528 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100400025; called by muse, mutect2
- PARP4 | c.2905T>C p.S969P | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.369); catalogued as COSV101131585; called by muse, mutect2, varscan2
- PASD1 | c.1440G>A p.Q480= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100949318; called by muse, mutect2, varscan2
- PCDHA12 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV56510774; called by muse, mutect2, varscan2
- PCDHA4 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs782455641, COSV63543263; called by muse, varscan2
- PCDHB3 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782801316, COSV50589763; called by muse, mutect2, varscan2
- PCDHB8 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); catalogued as rs782003552, COSV50754292; called by muse, mutect2, varscan2
- PCDHGA1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as rs1237215414, COSV65295658; called by muse, mutect2, varscan2
- PCID2 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371915766, COSV99872451; called by muse, mutect2, varscan2
- PDE11A | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1045114170, COSV99612052; called by muse, mutect2, varscan2
- PDE6C | c.1381A>T p.K461* | Nonsense Mutation (SNP) | VAF 56/321 reads (17%) | catalogued as COSV101008717; called by muse, mutect2, varscan2
- PGBD5 | c.287C>T p.T96M (on ENST00000525115; = p.T165M on NM_001258311.2) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs534656022, COSV58411437; called by muse, mutect2, varscan2
- PHF3 | c.2910dup p.R971Sfs*6 | Frame Shift Ins (INS) | VAF 21/110 reads (19%) | catalogued as rs755026826; called by mutect2, varscan2
- PIK3C2G | c.2516del p.N839Mfs*16 (on ENST00000676171; = p.N798Mfs*16 on NM_004570.5) | Frame Shift Del (DEL) | VAF 30/107 reads (28%) | catalogued as rs1229278001; called by mutect2, pindel, varscan2
- PLCG2 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs926237449, COSV100842120, COSV63875469; called by muse, mutect2, varscan2
- PLEKHA2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751041165, COSV66242477, COSV66242650; called by muse, mutect2, varscan2
- PLK1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267164; called by muse, mutect2, varscan2
- PLOD2 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs368177696; called by muse, varscan2
- PNLIP | c.1236G>T p.L412F | Missense Mutation (SNP) | VAF 86/441 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100981785; called by muse, mutect2, varscan2
- POGLUT1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99809567; called by muse, mutect2, varscan2
- POLN | c.1013G>A p.W338* | Nonsense Mutation (SNP) | VAF 48/251 reads (19%) | catalogued as rs754691451, COSV101242505; called by muse, mutect2, varscan2
- POLR3D | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs967660557, COSV100120080; called by muse, varscan2
- PPFIA1 | c.865A>T p.T289S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs1282738471, COSV99557351; called by muse, mutect2, varscan2
- PPM1D | c.1255G>A p.V419I | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100010837; called by muse, mutect2, varscan2
- PPM1L | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV55560921, COSV99861825; called by muse, mutect2, varscan2
- PPP1R3C | c.474_477del p.C158Wfs*11 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | catalogued as rs748227180; called by pindel, varscan2
- PPP3CA | c.230del p.N77Ifs*22 | Frame Shift Del (DEL) | VAF 25/177 reads (14%) | catalogued as rs1250808026; called by mutect2, pindel, varscan2
- PRDM10 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484112394, COSV58799636; called by muse, mutect2, varscan2
- PRICKLE3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376861498, COSV100889883; called by muse, mutect2, varscan2
- PRKDC | c.10844C>T p.A3615V | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV58066585; called by muse, mutect2, varscan2
- PTBP3 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV99270238; called by muse, mutect2, varscan2
- PTPN13 | c.855del p.K285Nfs*45 | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | catalogued as rs754278242; called by mutect2, varscan2
- PTPN13 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs529404601, COSV57402113; called by muse, mutect2, varscan2
- PTPN9 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963719922; called by muse, mutect2
- PTPRD | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs376714429; called by muse, mutect2, varscan2
- PXDNL | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs200870550, CM1410450, COSV62496137; called by muse, mutect2, varscan2
- RAB3D | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708827; called by muse, mutect2, varscan2
- RAB4A | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1416962296, COSV100797048; called by muse, mutect2, varscan2
- RAPGEF2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52427297; called by muse, mutect2, varscan2
- RBM25 | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV56201325; called by muse, mutect2, varscan2
- RDH16 | c.815T>G p.L272R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100660101; called by muse, mutect2, varscan2
- REV1 | c.2861T>C p.V954A | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1449636445, COSV99177198; called by muse, mutect2, varscan2
- RIF1 | c.4327C>T p.R1443* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV54623911; called by muse, mutect2, varscan2
- RIMBP2 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs368697814; called by muse, mutect2, varscan2
- RIMS1 | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 42/234 reads (18%) | catalogued as COSV99326386; called by muse, mutect2, varscan2
- RIPK1 | c.1685C>T p.T562M | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs367576973; called by muse, mutect2, varscan2
- RNF144A | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs758418992, COSV100305595; called by muse, mutect2, varscan2
- RNF43 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs747371137, COSV68458423; called by muse, mutect2, varscan2
- RNF6 | c.478A>G p.R160G | Missense Mutation (SNP) | VAF 52/363 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV100644625; called by muse, mutect2, varscan2
- RNGTT | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs759501463, COSV99666350; called by muse, mutect2, varscan2
- RPL10L | c.329G>T p.R110M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100022544; called by muse, mutect2, varscan2
- RPS6KA5 | c.1511_1513del p.G504del | In Frame Del (DEL) | VAF 18/108 reads (17%) | catalogued as rs767419873; called by pindel, varscan2
- RPUSD4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53600464; called by muse, mutect2, varscan2
- RTTN | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99732177; called by muse, mutect2, varscan2
- RYR1 | c.10577C>T p.A3526V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs374061380, COSV100615550; ClinVar: uncertain significance; called by muse, mutect2
- RYR3 | c.6710del p.G2237Efs*56 (on ENST00000389232; = p.G2237Efs*57 on NM_001036.6) | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs751516213; called by mutect2, pindel
- S100A13 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.141); catalogued as COSV52679818, COSV52679823; called by muse, mutect2, varscan2
- SACS | c.10453del p.I3485Lfs*10 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as rs1052973590; called by mutect2, pindel, varscan2
- SAMD4A | c.1701T>A p.Y567* | Nonsense Mutation (SNP) | VAF 29/160 reads (18%) | catalogued as COSV99200642; called by muse, mutect2, varscan2
- SCAF1 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100862140; called by muse, mutect2, varscan2
- SCAF11 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991973393, COSV101014316; called by muse, mutect2, varscan2
- SEC14L3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761871849, COSV99307137; called by muse, mutect2, varscan2
- SEC16A | c.4513G>A p.D1505N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763211212, COSV51542637; called by muse, mutect2, varscan2
- SELENOI | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53144187; called by muse, mutect2, varscan2
- SELENOT | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs753546569, COSV101517711; called by muse, mutect2, varscan2
- SEMA5B | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52098645; called by muse, mutect2, varscan2
- SEPTIN14 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101193318; called by muse, mutect2, varscan2
- SFMBT1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs558266493, COSV99966045; called by muse, mutect2, varscan2
- SGIP1 | c.1699A>G p.T567A | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV52780804; called by muse, mutect2, varscan2
- SHMT1 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV57400904; called by muse, mutect2, varscan2
- SHQ1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 73/372 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201983708, COSV57766890; called by muse, mutect2, varscan2
- SIDT1 | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV99333806; called by muse, mutect2, varscan2
- SLC2A10 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100826362; called by muse, mutect2
- SLC2A2 | c.421T>G p.L141V | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100049291; called by muse, varscan2
- SLC30A9 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs144935504; called by muse, mutect2, varscan2
- SLC38A3 | c.1401del p.I469Sfs*13 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV68844080; called by mutect2, pindel, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A9 | c.2737del p.L913Sfs*28 (on ENST00000507527 / NM_001258428.2; = p.L889Sfs*28 on NM_031467.3) | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs1157562442, COSV99140111; called by mutect2, pindel, varscan2
- SLC5A12 | c.724A>C p.T242P | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV54825709; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs748349403; called by pindel, varscan2
- SLIT2 | c.3341C>A p.S1114Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV99883426; called by muse, mutect2, varscan2
- SLTM | c.2389G>A p.V797I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV100998652; called by muse, mutect2
- SMARCA1 | c.2503A>T p.I835F | Missense Mutation (SNP) | VAF 65/523 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV100946501; called by muse, mutect2, varscan2
- SMARCAD1 | c.2285T>A p.I762N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as COSV100758897; called by muse, mutect2, varscan2
- SMYD1 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs186217134; called by muse, mutect2, varscan2
- SOD2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100496619; called by muse, mutect2, varscan2
- SOX6 | c.1269G>T p.Q423H (on ENST00000528429 / NM_001145819.2; = p.Q382H on NM_017508.3) | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100322028; called by muse, mutect2, varscan2
- SPDL1 | c.1175A>G p.Q392R | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99517512; called by muse, mutect2, varscan2
- SPPL2C | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs1460272713, COSV100234026, COSV61293180; called by muse, mutect2, varscan2
- SPTA1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs565907779, COSV63749834, COSV63750786; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 43/238 reads (18%) | PolyPhen possibly damaging (0.692); catalogued as rs369940675; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- SUPT5H | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs369717101, COSV100782093; called by muse, mutect2, varscan2
- SUPT6H | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.122); catalogued as COSV100112158; called by muse, mutect2, varscan2
- SYDE2 | c.2918T>C p.M973T | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100415901; called by muse, mutect2, varscan2
- SYNC | c.1090A>G p.T364A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.642); catalogued as COSV100995286; called by muse, mutect2, varscan2
- TAS2R16 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 107/496 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.223); catalogued as COSV99972236; called by muse, mutect2, varscan2
- TBC1D4 | c.1080+2T>C p.X360_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100884593; called by muse, varscan2
- TCERG1 | c.841T>C p.S281P | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.91); catalogued as COSV99694758; called by muse, mutect2, varscan2
- TCHH | c.3487C>T p.R1163C | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs1254693549, COSV64275591; called by muse, mutect2, varscan2
- TENM1 | c.4921G>A p.A1641T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100949895; called by muse, mutect2, varscan2
- TEX15 | c.1388G>T p.S463I (on ENST00000256246; = p.S846I on NM_001350162.2) | Missense Mutation (SNP) | VAF 69/282 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV99821266; called by muse, mutect2, varscan2
- THSD7B | c.1524del p.G509Dfs*58 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | catalogued as rs1236522898, COSV55712401; called by mutect2, pindel, varscan2
- TM7SF3 | c.1600C>A p.P534T | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100544790; called by muse, mutect2, varscan2
- TMC3 | c.1846T>C p.S616P | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845903; called by muse, mutect2, varscan2
- TMEM18 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV99806149; called by muse, mutect2, varscan2
- TMPRSS12 | c.189T>G p.D63E | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV101269104; called by muse, mutect2, varscan2
- TNC | c.3962C>A p.P1321H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV100405650; called by mutect2, varscan2
- TNFRSF9 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.098); catalogued as rs145966863; called by muse, mutect2, varscan2
- TNFSF12 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs1225175840, COSV99547222; called by muse, varscan2
- TNNI1 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60190720; called by muse, mutect2, varscan2
- TOP3A | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.021); catalogued as rs755827699, COSV100329057; called by muse, mutect2
- TP53BP2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376720051; called by muse, mutect2, varscan2
- TRIM41 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100163219; called by muse, mutect2
- TRIP4 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as rs144113386; called by muse, mutect2, varscan2
- TRMT9B | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs766632690, COSV67948541; called by muse, varscan2
- TRRAP | c.7024A>G p.M2342V (on ENST00000359863 / NM_001244580.1; = p.M2324V on NM_003496.3) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100722418; called by muse, mutect2, varscan2
- TSC2 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54767256, COSV54782411; called by muse, mutect2, varscan2
- TSHR | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 118/669 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as rs769777295, COSV53335974, COSV99991740; called by muse, mutect2, varscan2
- TSPAN6 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100885826; called by muse, mutect2, varscan2
- TTN | c.51129C>T p.C17043= (on ENST00000591111; = p.C9619= on NM_003319.4) | Splice Region (SNP) | VAF 10/70 reads (14%) | catalogued as COSV60435824; called by muse, mutect2
- TUBB1 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99414046; called by muse, mutect2, varscan2
- UBA6 | c.396C>G p.Y132* | Nonsense Mutation (SNP) | VAF 47/250 reads (19%) | catalogued as COSV100451682; called by muse, mutect2, varscan2
- UIMC1 | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101022131; called by muse, mutect2, varscan2
- ULK4 | c.3322C>T p.L1108F | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100092277; called by muse, mutect2
- USP10 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs538632016, COSV54751951; called by muse, mutect2, varscan2
- USP29 | c.1586T>C p.V529A | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99518045; called by muse, mutect2, varscan2
- USP53 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 75/347 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.3); catalogued as rs755943510, COSV99917683; called by muse, mutect2, varscan2
- USP7 | c.304A>C p.M102L | Missense Mutation (SNP) | VAF 83/424 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV100784171; called by muse, mutect2, varscan2
- UTP20 | c.5168A>G p.E1723G | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99880988; called by muse, mutect2
- VASP | c.910+1G>A p.X304_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99840967; called by muse, mutect2
- VKORC1L1 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100663160; called by muse, mutect2, varscan2
- VPS13A | c.5347G>A p.E1783K | Missense Mutation (SNP) | VAF 102/553 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100652650; called by muse, varscan2
- VPS41 | c.575T>C p.V192A | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99730867; called by muse, mutect2, varscan2
- WASHC4 | c.1384A>G p.M462V | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100162415; called by muse, mutect2, varscan2
- WDR1 | c.1319G>A p.S440N (on ENST00000382452; = p.S300N on NM_005112.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101221111; called by muse, mutect2, varscan2
- WDR36 | c.1943C>A p.T648N | Missense Mutation (SNP) | VAF 82/424 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101550965; called by muse, mutect2, varscan2
- WDR91 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs752551859, COSV100615681; called by muse, mutect2, varscan2
- WDTC1 | c.1594G>A p.G532S (on ENST00000319394 / NM_001276252.2; = p.G531S on NM_015023.5) | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1171296628, COSV100088822; called by muse, mutect2, varscan2
- WIPF2 | c.1288C>A p.R430S | Missense Mutation (SNP) | VAF 86/471 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100063525, COSV100063743; called by muse, mutect2, varscan2
- XG | c.158A>T p.Y53F | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.022); catalogued as COSV101150791; called by muse, mutect2, varscan2
- XPO4 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 34/133 reads (26%) | catalogued as COSV99688517; called by muse, mutect2, varscan2
- XYLT1 | c.2294A>G p.E765G | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358328447, COSV99761589; called by muse, mutect2, varscan2
- YIPF3 | c.428T>A p.V143D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58307462; called by muse, mutect2, varscan2
- YLPM1 | c.6220G>A p.A2074T | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV100353838; called by muse, mutect2, varscan2
- YTHDC1 | c.1224A>T p.K408N (on ENST00000344157 / NM_001031732.4; = p.K390N on NM_133370.4) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100704695; called by muse, mutect2, varscan2
- ZBBX | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 119/573 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as COSV100283886; called by muse, mutect2, varscan2
- ZBTB33 | c.1501A>G p.R501G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100434162; called by muse, mutect2, varscan2
- ZCCHC14 | c.1309G>A p.D437N (on ENST00000268616; = p.D574N on NM_015144.3) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs1567508449, COSV99233862; called by muse, mutect2, varscan2
- ZDHHC18 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765667318, COSV65145479; called by muse, mutect2, varscan2
- ZDHHC3 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368475280; called by muse, mutect2, varscan2
- ZEB2 | c.47A>G p.K16R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100355939, COSV57951666; called by muse, mutect2
- ZMYM2 | c.3622G>T p.G1208* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | catalogued as COSV101243706; called by muse, mutect2, varscan2
- ZMYND8 | c.2642C>T p.T881M (on ENST00000311275 / NM_001363741.2; = p.T855M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs373435522, COSV53683773; called by muse, mutect2, varscan2
- ZNF256 | c.1484A>G p.E495G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV99990793; called by muse, mutect2, varscan2
- ZNF34 | c.1513T>C p.C505R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603280; called by muse, mutect2, varscan2
- ZNF385A | c.736C>T p.P246S (on ENST00000338010 / NM_001130967.3; = p.P226S on NM_015481.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.281); catalogued as rs1356292273, COSV100566829; called by muse, mutect2, varscan2
- ZNF423 | c.3558G>T p.E1186D (on ENST00000563137 / NM_001379286.1; = p.E1178D on NM_015069.4) | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.182); catalogued as COSV99281428; called by muse, mutect2, varscan2
- ZNF43 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100731801; called by muse, mutect2, varscan2
- ZNF486 | c.377G>C p.C126S | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV100631243, COSV58721462; called by muse, mutect2, varscan2
- ZNF57 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV100182889, COSV60982824; called by muse, mutect2, varscan2
- ZNF586 | c.1004A>G p.H335R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101197679; called by muse, mutect2, varscan2
- ZNF765 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV101125460; called by muse, mutect2, varscan2
- ZNF91 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV100322636; called by muse, varscan2
- ZSCAN5B | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs368972539; called by muse, varscan2
- ACSS2 | c.1394_1396del p.F465del | In Frame Del (DEL) | VAF 22/82 reads (27%) | called by mutect2, pindel, varscan2
- ADAM29 | c.717dup p.G240Wfs*3 | Frame Shift Ins (INS) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- AK5 | c.194_196del p.K65del (on ENST00000354567 / NM_174858.3; = p.K39del on NM_012093.4) | In Frame Del (DEL) | VAF 10/94 reads (11%) | called by pindel, varscan2
- AKAP13 | c.3588dup p.T1197Hfs*9 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- ANGPTL5 | c.873del p.E292Kfs*30 | Frame Shift Del (DEL) | VAF 76/219 reads (35%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.4577dup p.N1526Kfs*7 | Frame Shift Ins (INS) | VAF 38/159 reads (24%) | called by mutect2, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- ASB18 | c.1336del p.L446Cfs*? | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by mutect2, pindel, varscan2
- BPHL | c.342dup p.E115* | Frame Shift Ins (INS) | VAF 37/226 reads (16%) | called by mutect2, pindel, varscan2
- BRD2 | c.113_116del p.L38Rfs*47 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- CALM2 | c.52del p.S18Hfs*11 | Frame Shift Del (DEL) | VAF 36/229 reads (16%) | called by mutect2, pindel, varscan2
- CASD1 | c.2347del p.C783Vfs*21 | Frame Shift Del (DEL) | VAF 40/255 reads (16%) | called by mutect2, pindel, varscan2
- CASK | c.2270del p.N757Tfs*40 (on ENST00000378163 / NM_001367721.1; = p.N752Tfs*40 on NM_003688.3) | Frame Shift Del (DEL) | VAF 97/681 reads (14%) | called by mutect2, pindel, varscan2
- CD44 | c.1686_1687del p.H563Lfs*17 | Frame Shift Del (DEL) | VAF 38/238 reads (16%) | called by pindel, varscan2
- CFAP299 | c.675del p.F225Lfs*21 | Frame Shift Del (DEL) | VAF 28/219 reads (13%) | called by mutect2, pindel, varscan2
- CYLC2 | c.630del p.G211Efs*22 | Frame Shift Del (DEL) | VAF 36/183 reads (20%) | called by mutect2, pindel, varscan2
- DAG1 | c.1256del p.P419Lfs*88 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- DDX60 | c.3580del p.T1194Pfs*8 | Frame Shift Del (DEL) | VAF 122/567 reads (22%) | called by mutect2, varscan2
- DIP2B | c.2760_2761del p.F921Sfs*62 | Frame Shift Del (DEL) | VAF 20/154 reads (13%) | called by pindel, varscan2
- DOCK1 | c.2910_2912del p.I970del | In Frame Del (DEL) | VAF 33/157 reads (21%) | called by pindel, varscan2
- DOCK4 | c.3975del p.K1325Nfs*6 | Frame Shift Del (DEL) | VAF 22/136 reads (16%) | called by mutect2, pindel, varscan2
- EFCAB5 | c.2251del p.I751* | Frame Shift Del (DEL) | VAF 71/404 reads (18%) | called by mutect2, varscan2
- EOMES | c.995del p.G332Afs*4 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- EPHA5 | c.242dup p.N81Kfs*8 | Frame Shift Ins (INS) | VAF 16/136 reads (12%) | called by mutect2, pindel, varscan2
- ERAP1 | c.1750del p.T584Qfs*21 | Frame Shift Del (DEL) | VAF 32/231 reads (14%) | called by mutect2, pindel, varscan2
- FBXO21 | c.1736_1737del p.H579Pfs*2 (on ENST00000330622 / NM_033624.3; = p.H572Pfs*2 on NM_015002.3) | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by pindel, varscan2
- FER | c.1428del p.K476Nfs*53 | Frame Shift Del (DEL) | VAF 14/113 reads (12%) | called by mutect2, pindel, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, pindel, varscan2
- GDAP2 | c.165del p.V56Wfs*11 | Frame Shift Del (DEL) | VAF 40/174 reads (23%) | called by mutect2, pindel, varscan2
- GSPT2 | c.1692del p.K564Nfs*13 | Frame Shift Del (DEL) | VAF 23/131 reads (18%) | called by mutect2, pindel, varscan2
- ILDR2 | c.470del p.N157Mfs*117 | Frame Shift Del (DEL) | VAF 32/150 reads (21%) | called by mutect2, pindel, varscan2
- INO80 | c.3544G>T p.G1182C | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JARID2 | c.3216del p.E1073Kfs*106 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- KANSL1L | c.2496dup p.Y833Ifs*2 | Frame Shift Ins (INS) | VAF 49/309 reads (16%) | called by mutect2, pindel, varscan2
- KANSL1L | c.1186del p.I396Sfs*4 | Frame Shift Del (DEL) | VAF 56/332 reads (17%) | called by mutect2, pindel, varscan2
- KIF21A | c.1299_1301del p.N434del | In Frame Del (DEL) | VAF 64/345 reads (19%) | called by pindel, varscan2
- KRT222 | c.121del p.M41Wfs*8 | Frame Shift Del (DEL) | VAF 32/166 reads (19%) | called by mutect2, pindel, varscan2
- LATS1 | c.3117del p.F1039Lfs*19 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- MASTL | c.1173del p.K391Nfs*12 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | called by mutect2, pindel, varscan2
- MGA | c.1246_1249del p.N416Vfs*7 | Frame Shift Del (DEL) | VAF 45/245 reads (18%) | called by mutect2, pindel, varscan2
- MUC5B | c.6117del p.S2040Pfs*51 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- NGLY1 | c.301dup p.I101Nfs*3 | Frame Shift Ins (INS) | VAF 63/306 reads (21%) | called by mutect2, pindel, varscan2
- OGA | c.1809del p.I604Lfs*17 | Frame Shift Del (DEL) | VAF 41/214 reads (19%) | called by mutect2, pindel, varscan2
- OR5AR1 | c.312del p.F104Lfs*2 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, varscan2
- OR6K2 | c.911del p.K304Sfs*3 | Frame Shift Del (DEL) | VAF 61/259 reads (24%) | called by mutect2, pindel, varscan2
- PARD3 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 19/528 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- PAXBP1 | c.2499dup p.K834Qfs*32 | Frame Shift Ins (INS) | VAF 20/120 reads (17%) | called by mutect2, pindel, varscan2
- PDGFRL | c.755dup p.R253Qfs*63 | Frame Shift Ins (INS) | VAF 17/123 reads (14%) | called by mutect2, pindel, varscan2
- PIK3CB | c.3009_3010del p.F1004Cfs*10 | Frame Shift Del (DEL) | VAF 37/236 reads (16%) | called by pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel
- PNPT1 | c.1708del p.I570Lfs*2 | Frame Shift Del (DEL) | VAF 32/208 reads (15%) | called by mutect2, pindel, varscan2
- PPP2R5E | c.1347del p.K449Nfs*7 | Frame Shift Del (DEL) | VAF 162/883 reads (18%) | called by mutect2, pindel, varscan2
- PTDSS1 | c.1316C>A p.S439Y | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.063); called by muse, mutect2
- RBM15 | c.851del p.P284Lfs*98 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- REPS1 | c.1649del p.P550Lfs*14 (on ENST00000450536 / NM_001286611.2; = p.P549Lfs*14 on NM_031922.4) | Frame Shift Del (DEL) | VAF 33/204 reads (16%) | called by mutect2, pindel, varscan2
- RIOK1 | c.1596dup p.E533Rfs*20 | Frame Shift Ins (INS) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- SENP6 | c.2590del p.I864* | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, varscan2
- SLC24A3 | c.1020del p.K341Rfs*11 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- ST6GALNAC5 | c.515del p.G172Afs*21 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- STK11IP | c.1620del p.L541Cfs*50 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- SUDS3 | c.303dup p.L102Tfs*21 | Frame Shift Ins (INS) | VAF 12/108 reads (11%) | called by mutect2, pindel, varscan2
- SYNE2 | c.4404del p.K1468Nfs*3 | Frame Shift Del (DEL) | VAF 29/150 reads (19%) | called by mutect2, pindel, varscan2
- TAF2 | c.3006del p.A1003Lfs*3 | Frame Shift Del (DEL) | VAF 56/309 reads (18%) | called by mutect2, pindel, varscan2
- TAS2R20 | c.442del p.H148Tfs*4 | Frame Shift Del (DEL) | VAF 35/144 reads (24%) | called by mutect2, pindel, varscan2
- TCF12 | c.1419_1428del p.V474Mfs*18 | Frame Shift Del (DEL) | VAF 19/129 reads (15%) | called by mutect2, pindel, varscan2
- TDRD5 | c.1236del p.K412Nfs*17 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | called by mutect2, pindel, varscan2
- TNRC6C | c.2777del p.K926Rfs*3 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- TRAV22 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRIM29 | c.1207del p.E403Rfs*7 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by pindel, varscan2
- TTC12 | c.669del p.A224Qfs*20 | Frame Shift Del (DEL) | VAF 24/133 reads (18%) | called by mutect2, pindel, varscan2
- TTK | c.575del p.K192Sfs*18 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, varscan2
- TTN | c.48377_48378del p.P16126Rfs*3 (on ENST00000591111; = p.P8702Rfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 23/170 reads (14%) | called by mutect2, pindel, varscan2
- UBR1 | c.4841del p.P1614Hfs*32 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- USP45 | c.603del p.F201Lfs*17 | Frame Shift Del (DEL) | VAF 52/184 reads (28%) | called by mutect2, varscan2
- WASHC4 | c.1707+1del | Frame Shift Del (DEL) | VAF 25/176 reads (14%) | called by mutect2, pindel, varscan2
- XK | c.999_1001dup p.L334dup | In Frame Ins (INS) | VAF 45/240 reads (19%) | called by mutect2, varscan2
- XRN1 | c.4831del p.R1611Gfs*34 | Frame Shift Del (DEL) | VAF 60/265 reads (23%) | called by mutect2, pindel, varscan2
- ZBTB25 | c.733dup p.E245Gfs*4 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- ZDHHC7 | c.837del p.S280Hfs*5 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, varscan2
- ZNF518A | c.3760dup p.I1254Nfs*11 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- ZNF674 | c.1512del p.A505Pfs*32 | Frame Shift Del (DEL) | VAF 84/475 reads (18%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.3904A>C p.R1302= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV53246349, COSV99484900; called by mutect2, varscan2
- ADGRD1 | c.624C>T p.L208= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs1372101413, COSV99895236; called by muse, mutect2, varscan2
- AF196969.1 | c.261C>T p.Y87= | Silent (SNP) | VAF 49/236 reads (21%) | catalogued as rs145509273, COSV99339333; called by muse, mutect2, varscan2
- AK5 | c.987A>G p.S329= (on ENST00000354567 / NM_174858.3; = p.S303= on NM_012093.4) | Silent (SNP) | VAF 88/445 reads (20%) | catalogued as rs750566495, COSV100642637; called by muse, mutect2, varscan2
- ANLN | c.2346C>T p.N782= | Silent (SNP) | VAF 47/293 reads (16%) | catalogued as rs772500301, COSV99732226; called by muse, mutect2, varscan2
- ARID4A | c.2856C>T p.I952= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1322829485, COSV100794207; called by muse, mutect2, varscan2
- ARNT | c.2064G>A p.S688= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs777963072, COSV100591125; called by muse, mutect2, varscan2
- ATP1A3 | c.2448C>T p.G816= (on ENST00000545399 / NM_001256214.2; = p.G803= on NM_152296.5) | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs781856091, COSV100132225; called by muse, varscan2
- ATP6V0A2 | c.840C>T p.T280= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs139680786, CD080792; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ATP9A | c.1428C>T p.N476= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs748710406, COSV100124906, COSV58768983; called by muse, mutect2, varscan2
- B4GALNT2 | c.1053C>T p.T351= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs570206637, COSV100302316, COSV55925934; called by muse, mutect2, varscan2
- BCL9 | c.3834C>T p.G1278= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs372808042; called by muse, mutect2
- BOD1L1 | c.6753C>T p.D2251= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs775645849, COSV50028266; called by muse, mutect2, varscan2
- BTAF1 | c.24C>T p.R8= | Silent (SNP) | VAF 56/376 reads (15%) | catalogued as COSV99795262; called by muse, mutect2, varscan2
- C3AR1 | c.1014C>T p.I338= | Silent (SNP) | VAF 72/310 reads (23%) | catalogued as rs865828397, COSV99368463; called by muse, mutect2, varscan2
- CD38 | c.153C>T p.S51= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs763737168, COSV99882627; called by mutect2, varscan2
- CFAP298-TCP10L | c.567G>A p.A189= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs746490682, COSV99267241; called by muse, mutect2, varscan2
- CHAT | c.1320C>T p.C440= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs766466820, COSV100340082; called by muse, mutect2
- CHD7 | c.1620C>A p.L540= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as COSV101418220; called by muse, mutect2, varscan2
- CHST1 | c.337C>A p.R113= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100346207; called by mutect2, varscan2
- CNTROB | c.1761C>T p.P587= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs146923091; called by mutect2, varscan2
- COG7 | c.1785G>A p.L595= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100207541; called by muse, mutect2, varscan2
- COL11A1 | c.2724C>T p.G908= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs201972285, COSV62182500; called by muse, mutect2, varscan2
- COL17A1 | c.792G>A p.A264= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs766821472, COSV100793155; called by muse, varscan2
- DAB2 | c.981G>A p.S327= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs753430742, COSV57914602; called by muse, mutect2, varscan2
- DERL1 | c.340T>C p.L114= | Silent (SNP) | VAF 97/444 reads (22%) | catalogued as rs1257188037, COSV52366604; called by muse, mutect2, varscan2
- DGLUCY | c.630C>T p.Y210= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as rs748049947, COSV99824266; called by muse, mutect2, varscan2
- DLGAP5 | c.1500G>A p.E500= | Silent (SNP) | VAF 82/344 reads (24%) | catalogued as COSV99903874; called by muse, varscan2
- DMXL2 | c.8853T>C p.D2951= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV99196305; called by muse, mutect2
- DSEL | c.3267C>T p.F1089= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs745691476, COSV59489622, COSV59495451; called by muse, mutect2
- DYRK2 | c.351G>A p.T117= (on ENST00000344096 / NM_006482.3; = p.T44= on NM_003583.4) | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs376315832; called by muse, mutect2, varscan2
- DYSF | c.540G>C p.P180= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99246632; called by muse, mutect2, varscan2
- DZIP3 | c.2226C>T p.D742= | Silent (SNP) | VAF 43/310 reads (14%) | catalogued as COSV100847767; called by muse, mutect2, varscan2
- EIF5AL1 | c.159C>T p.H53= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1379612668, COSV101592809; called by mutect2, varscan2
- FARSA | c.822C>T p.H274= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs554119533, COSV58904560; called by muse, mutect2, varscan2
- FCHO2 | c.1587A>G p.S529= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as COSV100530582; called by muse, mutect2, varscan2
- FILIP1L | c.2769C>T p.T923= (on ENST00000354552 / NM_182909.3; = p.T683= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 87/517 reads (17%) | catalogued as rs373124183; called by muse, mutect2, varscan2
- FRMD1 | c.657C>T p.T219= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99349689, COSV99349708; called by muse, mutect2, varscan2
- GEMIN4 | c.414T>C p.H138= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV56747936; called by muse, mutect2, varscan2
- GKN1 | c.396C>T p.S132= | Silent (SNP) | VAF 20/137 reads (15%) | catalogued as COSV100933568; called by muse, mutect2, varscan2
- GPR158 | c.2724C>T p.S908= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs770498331, COSV66283644; called by muse, mutect2, varscan2
- GRM1 | c.432C>T p.G144= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99265912; called by muse, mutect2, varscan2
- H3C6 | c.333C>T p.C111= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs891371937, COSV64519566; called by muse, mutect2, varscan2
- HARS1 | c.561T>C p.P187= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV56909968; called by muse, mutect2, varscan2
- HERC1 | c.9564C>A p.T3188= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV101496532; called by muse, mutect2, varscan2
- HFM1 | c.3438T>G p.L1146= | Silent (SNP) | VAF 53/257 reads (21%) | catalogued as COSV99645921; called by muse, mutect2, varscan2
- IGHMBP2 | c.1479C>T p.T493= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs370367228, COSV99662045; called by muse, varscan2
- IGHV3-35 | c.204G>A p.S68= | Silent (SNP) | VAF 11/172 reads (6%) | catalogued as rs751443166; called by muse, mutect2
- IGSF9 | c.1794C>T p.I598= (on ENST00000368094 / NM_001135050.2; = p.I582= on NM_020789.4) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV63638861; called by muse, mutect2, varscan2
- IL21R | c.276C>T p.D92= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV61973026; called by muse, mutect2, varscan2
- INHBC | c.813C>T p.Y271= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs754703417, COSV59004978; called by muse, mutect2, varscan2
- IP6K2 | c.357T>C p.H119= | Silent (SNP) | VAF 46/217 reads (21%) | catalogued as COSV60792679; called by muse, mutect2, varscan2
- ITGBL1 | c.330T>C p.C110= | Silent (SNP) | VAF 63/320 reads (20%) | catalogued as COSV101095329; called by muse, mutect2, varscan2
- ITIH3 | c.1827C>T p.N609= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs375386244; called by muse, mutect2, varscan2
- ITPR1 | c.8040C>A p.A2680= (on ENST00000354582; = p.A2625= on NM_002222.7) | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- ITPR3 | c.2106G>A p.E702= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100967296; called by muse, mutect2, varscan2
- KCNJ10 | c.585C>T p.C195= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs1484203998, COSV100927915; called by muse, mutect2, varscan2
- KLC1 | c.984A>G p.E328= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV99871490; called by muse, varscan2
- KRT38 | c.372G>A p.Q124= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55847926; called by muse, mutect2, varscan2
- KRT79 | c.1188T>C p.R396= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100398422; called by muse, mutect2, varscan2
- LAMB1 | c.3684C>T p.S1228= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs762139899, COSV55962822, COSV55968621; called by muse, mutect2, varscan2
- LMX1A | c.570G>A p.K190= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV54218665; called by muse, mutect2, varscan2
- LNPEP | c.219A>G p.S73= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV99183527; called by muse, mutect2, varscan2
- LRIG3 | c.3294T>C p.C1098= | Silent (SNP) | VAF 40/236 reads (17%) | called by muse, mutect2, varscan2
- LRP1 | c.9003C>A p.G3001= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV99675645; called by muse, mutect2, varscan2
- MARCHF10 | c.24G>A p.R8= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100248125, COSV60889015; called by muse, mutect2, varscan2
- MDGA1 | c.199C>A p.R67= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV51791696, COSV99776803; called by muse, varscan2
- MEA1 | c.441A>G p.G147= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99775688; called by muse, mutect2, varscan2
- MICAL3 | c.2145C>T p.A715= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs750715153, COSV99261355; called by muse, mutect2, varscan2
- MOGAT2 | c.915C>T p.H305= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99549527; called by muse, varscan2
- MROH7 | c.3273G>A p.P1091= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs764525005, COSV100273388; called by muse, mutect2, varscan2
- MSH6 | c.693A>G p.V231= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV99315834; called by muse, mutect2, varscan2
- MTOR | c.1602C>T p.D534= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV100816113; called by muse, varscan2
- MUC16 | c.24654C>T p.D8218= | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as COSV101199709; called by muse, mutect2, varscan2
- MX2 | c.108C>T p.F36= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs766937760, COSV58094843; called by muse, mutect2, varscan2
- MYO1E | c.2961C>T p.S987= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99895369; called by muse, mutect2, varscan2
- NISCH | c.1767C>A p.P589= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100617299; called by muse, mutect2
- NUDT7 | c.60G>A p.K20= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV99216064, COSV99216094; called by muse, mutect2, varscan2
- OR5D16 | c.765C>T p.G255= | Silent (SNP) | VAF 33/222 reads (15%) | catalogued as COSV101003928; called by muse, mutect2, varscan2
- OTUD4 | c.906T>C p.N302= (on ENST00000447906 / NM_001366057.1; = p.N237= on NM_001102653.1) | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as COSV101485972; called by muse, mutect2, varscan2
- PARD3 | c.2811G>A p.A937= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as rs758182131, COSV100400882; called by muse, mutect2, varscan2
- PCDH11X | c.2838T>A p.P946= | Silent (SNP) | VAF 45/179 reads (25%) | catalogued as COSV100011443; called by muse, mutect2, varscan2
- PCDHGA2 | c.483C>T p.D161= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs780869328, COSV53999490; called by muse, mutect2, varscan2
- PCDHGA6 | c.1347G>A p.P449= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs757761874, COSV53908918; called by muse, mutect2, varscan2
- PCM1 | c.903T>C p.A301= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as COSV100279027; called by muse, mutect2, varscan2
- PIGG | c.723C>T p.S241= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs782415035, COSV99573853; called by muse, varscan2
- PIH1D1 | c.234C>T p.P78= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs772492086, COSV99221093; called by muse, mutect2, varscan2
- PIKFYVE | c.1764T>C p.H588= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as rs1173296905, COSV100010595; called by muse, mutect2, varscan2
- PKHD1 | c.972G>A p.Q324= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100582887; called by muse, mutect2, varscan2
- PKLR | c.663C>T p.D221= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs761145518, COSV61360475; called by muse, mutect2
- PLA2G12B | c.45G>T p.G15= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100888002; called by muse, mutect2, varscan2
- PLPPR4 | c.1944G>A p.K648= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs1557784621, COSV100926788; called by muse, mutect2, varscan2
- PMEL | c.783C>T p.D261= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100093016, COSV59384950; called by muse, mutect2, varscan2
- POLG | c.2712C>T p.D904= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs770458126, COSV51523392; called by muse, mutect2, varscan2
- POLR3B | c.2973C>T p.S991= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as rs747265286, COSV57284229; called by muse, mutect2, varscan2
- PORCN | c.735C>T p.Y245= (on ENST00000326194 / NM_203475.3; = p.Y234= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV58225822; called by muse, mutect2, varscan2
- PRCC | c.627G>A p.S209= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as rs757081137, COSV54857349; called by muse, mutect2, varscan2
- PRMT2 | c.576C>T p.Y192= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99388636; called by muse, mutect2, varscan2
- PROKR1 | c.606C>T p.T202= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs1008650835, COSV58138068; called by muse, mutect2, varscan2
- PROSER3 | c.786C>T p.A262= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV56554764; called by muse, varscan2
- PROX1 | c.1677C>T p.C559= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs755137171, COSV54778478; called by muse, mutect2, varscan2
- RDM1 | c.129C>T p.G43= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs755785027; called by muse, mutect2, varscan2
- REP15 | c.576G>A p.L192= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV99944769; called by muse, mutect2, varscan2
- RHOC | c.93G>A p.P31= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs372772606, COSV53517503; called by muse, mutect2, varscan2
- RNF111 | c.1545T>C p.H515= | Silent (SNP) | VAF 39/245 reads (16%) | catalogued as rs75252387, COSV62083576; called by muse, mutect2, varscan2
- ROBO4 | c.1308C>T p.C436= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100127558; called by muse, mutect2, varscan2
- RPGRIP1 | c.207T>C p.D69= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs757352536, COSV52858961; called by muse, mutect2, varscan2
- S100A7L2 | c.249C>A p.T83= | Silent (SNP) | VAF 43/238 reads (18%) | catalogued as COSV100906875; called by muse, mutect2, varscan2
- SCG2 | c.210T>C p.H70= | Silent (SNP) | VAF 157/844 reads (19%) | catalogued as rs1258770559, COSV100544712; called by muse, mutect2, varscan2
- SCP2D1 | c.363C>T p.G121= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99601994, COSV99602136; called by muse, mutect2, varscan2
- SFMBT2 | c.1341T>A p.T447= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100738950; called by muse, mutect2, varscan2
- SHROOM4 | c.4416C>A p.I1472= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV99173393; called by muse, mutect2, varscan2
- SLC5A11 | c.258C>A p.G86= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV100762768; called by muse, mutect2, varscan2
- SLC7A13 | c.372T>C p.F124= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs185522605, COSV52536834; called by muse, mutect2, varscan2
- SNX12 | c.135G>A p.A45= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99339896; called by muse, mutect2
- SNX8 | c.315G>A p.S105= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs774313343, COSV99770795; called by muse, mutect2, varscan2
- SPACA9 | c.9G>A p.E3= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1237963888, COSV62522165; called by muse, mutect2, varscan2
- SPRED2 | c.1071C>T p.P357= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as rs761279539, COSV100710181; called by muse, mutect2, varscan2
- SPRYD4 | c.432T>C p.G144= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100358329; called by muse, mutect2, varscan2
- SRPRA | c.1677C>T p.A559= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs761582671, COSV55006036, COSV55009404; called by muse, mutect2, varscan2
- SUGT1 | c.489T>C p.S163= (on ENST00000343788 / NM_001130912.3; = p.S131= on NM_006704.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/313 reads (14%) | catalogued as COSV59424191; called by muse, mutect2, varscan2
- SYNPO | c.1170G>A p.P390= (on ENST00000394243 / NM_001166208.2; = p.P146= on NM_007286.6) | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs367801557; called by muse, mutect2, varscan2
- TBC1D22A | c.1371C>T p.C457= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as rs372661631; called by muse, mutect2, varscan2
- TBX22 | c.936C>T p.G312= | Silent (SNP) | VAF 39/201 reads (19%) | catalogued as rs376686839, COSV64786596; ClinVar: likely benign; called by muse, mutect2, varscan2
- TCF7L2 | c.1653G>A p.P551= (on ENST00000355995 / NM_001367943.1; = p.P528= on NM_030756.5) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1173115336, COSV53335776; called by muse, mutect2, varscan2
- TDRD5 | c.2154T>C p.R718= | Silent (SNP) | VAF 18/346 reads (5%) | catalogued as COSV99676164; called by muse, mutect2
- TENM2 | c.2238C>T p.H746= (on ENST00000518659 / NM_001122679.2; = p.H514= on NM_001080428.3) | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs770869660, COSV69127470; called by muse, mutect2, varscan2
- TENT5D | c.486G>T p.V162= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as COSV100382695, COSV57638315; called by muse, mutect2, varscan2
- TIAM1 | c.1479C>T p.H493= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs773177454, COSV99734786; called by muse, mutect2, varscan2
- TLDC2 | c.235C>T p.L79= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV54116044; called by muse, mutect2
- TMEM179B | c.585G>A p.R195= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1565194249, COSV53671345; called by muse, mutect2, varscan2
- TMEM181 | c.189C>T p.V63= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs772693935, COSV65562103; called by muse, mutect2, varscan2
- TPR | c.3954C>T p.S1318= | Silent (SNP) | VAF 107/489 reads (22%) | catalogued as rs748820084, COSV66605807; called by muse, mutect2, varscan2
- TRIM16L | c.24T>G p.A8= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV101192600; called by muse, mutect2, varscan2
- TRIM28 | c.2154C>T p.R718= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs779230878, COSV99448961; called by muse, mutect2, varscan2
- TRIM67 | c.2190C>A p.L730= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100792111; called by muse, mutect2
- TTC8 | c.405C>A p.A135= (on ENST00000338104 / NM_001288781.1; = p.A145= on NM_144596.4) | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100581296; called by muse, mutect2, varscan2
- TTN | c.11502G>A p.Q3834= (on ENST00000591111; = p.Q3788= on NM_003319.4) | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV100610527; called by muse, mutect2, varscan2
- VPS13B | c.186T>C p.I62= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV62027340; called by mutect2, varscan2
- VPS35L | c.1668C>T p.H556= | Silent (SNP) | VAF 79/407 reads (19%) | catalogued as COSV51992854; called by muse, mutect2, varscan2
- WDR49 | c.576C>T p.N192= (on ENST00000308378 / NM_001366158.1; = p.N533= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as rs372277287; called by muse, mutect2, varscan2
- WNT4 | c.792G>A p.P264= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs938682094, COSV99268681; called by muse, mutect2, varscan2
- YES1 | c.276T>C p.G92= | Silent (SNP) | VAF 34/241 reads (14%) | catalogued as COSV100099512; called by muse, mutect2, varscan2
- YY2 | c.573C>T p.N191= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs959495609, COSV63412419; called by muse, mutect2, varscan2
- ZNF530 | c.1563C>T p.C521= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs551484617, COSV60532338; called by muse, mutect2, varscan2
- CPLANE1 | c.*2848G>A | 3'UTR (SNP) | VAF 45/230 reads (20%) | catalogued as rs752334335, COSV57052978; called by muse, mutect2, varscan2
- DCHS2 | n.3160C>A | RNA (SNP) | VAF 39/241 reads (16%) | catalogued as COSV100251689; called by muse, mutect2, varscan2
- DLEC1 | c.*7G>A | 3'UTR (SNP) | VAF 5/18 reads (28%) | catalogued as rs369229329; called by mutect2, varscan2
- MARCHF1 | c.163-63del | Intron (DEL) | VAF 22/150 reads (15%) | called by mutect2, varscan2
- MIR196A1 | n.50_52del | RNA (DEL) | VAF 18/66 reads (27%) | catalogued as rs759524926; called by pindel, varscan2
- MYB | c.1203+1204del | Intron (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- NRG1 | c.502+31353C>T | Intron (SNP) | VAF 22/298 reads (7%) | catalogued as rs777526753, COSV55156842; called by muse, mutect2
- OFCC1 | n.236G>A | RNA (SNP) | VAF 39/207 reads (19%) | catalogued as rs771878022; called by muse, mutect2, varscan2
- RNF213 | c.3024+103G>A | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as rs541581943, COSV100172970; called by muse, varscan2
- S1PR3 | c.-148+248G>A | Intron (SNP) | VAF 11/47 reads (23%) | catalogued as COSV57837538; called by muse, mutect2, varscan2
- SLIT2 | c.1463-582G>A | Intron (SNP) | VAF 50/294 reads (17%) | catalogued as rs539543647, COSV99883420; called by muse, mutect2, varscan2
- ZNF137P | n.1440A>G | RNA (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
